RC case RC-B5CQ — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7c23620a-318a-4f49-8eaa-ea0b91917a8a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1929; Vital status: Dead; Days to death: 549 days (1.5 years); Year of death: 2019; Cause of death: Cancer Related.

Diagnoses (2)
1. Prolymphocytic leukemia, T-cell type (the primary disease): ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 88.5 years (32,318 days); Year of diagnosis: 2017; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Peripheral blood.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ruxolitinib; Initial disease status: Initial Diagnosis; Days to treatment start: 142 days; Days to treatment end: 512 days (1.4 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Clinical trial indicator: Yes; Timepoint category: First Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Stopped Due to Toxicity; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Progression (histology not recorded by GDC). Age at diagnosis: 89.8 years (32,796 days); Days to diagnosis: 478 days (1.3 years).

Follow-up (2 entries)
- Day 478 (progression): Progression or recurrence: Yes; Days to progression: 478 days (1.3 years).
- Day 549 (end of treatment course 1): Disease response: With Tumor; Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- Lactate Dehydrogenase 554 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 74.4 kg; Height: 167.6 cm; BMI: 26.5.
- Timepoint category: Prior to Diagnosis; Comorbidities: Coronary Artery Disease.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1957; Tobacco smoking quit year: 1977.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Pancreas Cancer.

Biospecimens (2 samples)
- Sample RC-B5CQ-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B5CQ-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
